Somatic mutation profile of tumor specimen 0DWM1E from CCDI case PBCPCR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 11.4 years (4,149 days).
Specimen 0DWM1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 381cef91-18db-4c02-bed2-cb0056501687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWLYS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdfad801-74d3-478d-b248-94dfc79070dd

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 186/438 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 122/485 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMS19 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 69/1163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199857462; called by muse, mutect2
- PDCD1 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 120/316 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs530939318, COSV100545427; called by muse, mutect2, varscan2
- PPP1CA | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 161/445 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1305960330; called by muse, mutect2, varscan2
- RAD51AP2 | c.1537A>T p.I513F | Missense Mutation (SNP) | VAF 149/446 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1215266905, COSV67588149; called by muse, mutect2, varscan2
- WNK3 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 301/1334 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs1557155355, COSV63611911; called by muse, mutect2, varscan2
- ANKRD34C | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 301/694 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRR3 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 376/1053 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SERPINB9 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 249/625 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SKI | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 158/391 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST6 | c.231G>A p.A77= | Silent (SNP) | VAF 37/447 reads (8%) | catalogued as COSV56410653; called by muse, mutect2
- FRMPD4 | c.855C>T p.F285= | Silent (SNP) | VAF 391/1515 reads (26%) | called by muse, mutect2, varscan2
- PPP1CA | c.498C>T p.D166= | Silent (SNP) | VAF 184/464 reads (40%) | catalogued as rs766590370; called by muse, mutect2, varscan2
- ASXL1 | c.1720-12C>A | Intron (SNP) | VAF 88/204 reads (43%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- RUSC1 | c.*28C>A | 3'UTR (SNP) | VAF 110/291 reads (38%) | called by muse, mutect2, varscan2
